Somatic mutation profile of tumor specimen TCGA-AC-A2BM-01A (aliquot TCGA-AC-A2BM-01A-11D-A21Q-09) from TCGA case TCGA-AC-A2BM, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 41.6 years (15,212 days).
Specimen TCGA-AC-A2BM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5fcbaadb-1720-424a-8bca-97fb4ea5e51a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AC-A2BM-11A (Solid Tissue Normal), aliquot TCGA-AC-A2BM-11A-13D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c963743-a2a6-4f99-9bbc-396d65850950

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY5 | c.2441A>C p.K814T | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV59204029; called by muse, mutect2, varscan2
- ASTN1 | c.2933C>A p.T978N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62505638; called by muse, mutect2, varscan2
- ATXN7L2 | c.1111C>A p.P371T | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV60205938; called by muse, mutect2, varscan2
- B4GALT3 | c.776G>A p.G259D | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as COSV100157916; called by muse, mutect2, varscan2
- CAPN2 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.302); catalogued as COSV54339723; called by muse, mutect2, varscan2
- CES5A | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.933); catalogued as rs768951051, COSV51870413; called by muse, mutect2, varscan2
- COL11A1 | c.4106G>A p.G1369D | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV100617961; called by muse, mutect2
- NTRK2 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV52881003; called by muse, mutect2, varscan2
- PRKDC | c.1137A>C p.K379N | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV100042707, COSV58057040; called by muse, mutect2, varscan2
- SLC16A6 | c.285G>A p.M95I | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.124); catalogued as COSV59179370; called by muse, mutect2, varscan2
- SLC25A2 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs1344746171, COSV53403267; called by muse, mutect2
- TINAG | c.530G>A p.S177N | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV52514158, COSV99450784; called by muse, mutect2, varscan2
- NUP153 | c.2085T>A p.T695= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV50463861; called by muse, mutect2, varscan2
